FM case AD1210 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/dc8d08f6-1920-4b26-88ca-45df486b6b6f

Female, 44.8 years: Adenoid cystic carcinoma (ICD-O-3 8200/3). Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Tumor.
